Gene-level copy-number profile of tumor specimen TCGA-C5-A3HL-01A from TCGA case TCGA-C5-A3HL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G2; Age at diagnosis: 76.6 years (27,963 days).
Specimen TCGA-C5-A3HL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.482f975e-45f6-4105-8e33-89d1ca2e2117.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C5-A3HL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/837066f6-4f41-4b84-92a1-841fc775c693

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,276; copy number 2: 57,376; copy number 7: 1,168.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-C5-A3HL-01A-11D-A20T-01): tumor purity 0.66, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,168 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,678,934–198,222,513, 1,168 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,276. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
